Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAKO, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAKO-05A (Additional - New Primary).

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 1.7 cm; no angio-invasion; no invasion of rete testis; no invasion of tunica albuginea; epididymis and spermatic cord not present in the available slides.

Testistumor right (at the same time): seminoma, see

Date of procurement (= date of orchidectomy):

ICD-O-3
Seminoma NOS 9061/3
Site: @ Testis NOS
C62.9
W 3/5/14

pathologist

professor of pathology

2nd Primary.

Criteria	lw 1/23/14	Yes	No
Dual/Synchronous Primary Noted	Direct	/	

Source: NCI Genomic Data Commons file 8a0b9bb7-cfad-4a77-9557-59f2e3fec0b7 (TCGA-2G-AAKO.197C827B-BFF9-4C9F-9D76-D4617DA18658.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).